Surgical pathology report (de-identified scan), TCGA case TCGA-P8-A6RY, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of Pittsburgh, specimen TCGA-P8-A6RY-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:
ADRENAL GLAND, RIGHT, ADRENALECTOMY (17 grams) -
PHEOCHROMOCYTOMA (3.7 CM).

Source: NCI Genomic Data Commons file 7176b3ef-9e91-439d-b398-d2ed2cc349f2 (TCGA-P8-A6RY.BC5DD88B-6A99-4AD9-90C2-07B2897FAD5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).